Gene-level copy-number profile of tumor specimen ALCH-B42U-TTP1-A from ALCHEMIST case ALCH-B42U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,337 days).
Specimen ALCH-B42U-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2fbea334-fa03-4abc-84f8-dde6c49477ed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B42U-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/c08cd19b-9ca5-4db0-a6e6-4367ae529e31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 10,522; copy number 2: 45,053; copy number 3: 2,262; copy number 4: 236; copy number 5: 176; copy number 6: 520; copy number 7: 103; copy number 10: 11.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,478,775–41,484,683, 1 gene: EDN2.
- chr6:27,865,317–27,873,534, 4 genes (within-gene range 0–2): H2AC16, H1-5, H3C11, H4C13.
- chr6:81,491,439–82,169,391, 10 genes: TENT5A, AL122017.1, AL359693.1, RNA5SP210, AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1.
- chr7:76,818,377–76,919,191, 2 genes: AC006972.1, AC007003.1.
- chr7:159,006,522–159,030,195, 1 gene (within-gene range 0–2): LINC00689.
- chr10:133,344,643–133,350,726, 2 genes (within-gene range 0–2): BANF1P2, AL360181.1.
- chr11:48,959,928–48,961,810, 1 gene: AC027369.2.
- chr16:1,512,979–1,514,675, 1 gene (within-gene range 0–2): AL031705.1.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.
- chr19:10,922,185–10,928,681, 1 gene (within-gene range 0–1): YIPF2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 374 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:71,841,549–78,956,082, 97 genes, copy number 6–7 (broad region; genes not listed).
- chr8:81,439,436–85,540,511, 54 genes, copy number 6: AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1.
- chr8:125,648,327–126,008,930, 1 gene, copy number 5 (within-gene range 2–5): AC016074.2.
- chr8:125,859,721–126,292,788, 1 gene, copy number 5 (within-gene range 2–5): LINC00861.
- chr8:125,951,861–134,979,279, 123 genes, copy number 5–6 (broad region; genes not listed).
- chr8:143,915,153–144,792,587, 66 genes, copy number 5–6 (broad region; genes not listed).
- chr8:144,876,497–145,066,685, 9 genes, copy number 7: ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr20:63,939,829–64,327,972, 23 genes, copy number 5: UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 8,189. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
